Somatic mutation profile of tumor specimen TCGA-Y6-A9XI-01A (aliquot TCGA-Y6-A9XI-01A-11D-A41K-08) from TCGA case TCGA-Y6-A9XI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.5 years (26,471 days).
Specimen TCGA-Y6-A9XI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa0e468f-2b69-4635-92e1-e408b3d7c961.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Y6-A9XI-10A (Blood Derived Normal), aliquot TCGA-Y6-A9XI-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecd98862-5050-4cd6-b53d-5c3a32e0f14d

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Frame Shift Del 2, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.2851G>A p.E951K (on ENST00000272895 / NM_173076.3; = p.E633K on NM_015657.3) | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1353723813, COSV55948964; called by muse, mutect2
- AHNAK2 | c.13486G>A p.D4496N | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs760149560, COSV60912529; called by muse, mutect2
- ANAPC1 | c.4868A>C p.D1623A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV100594516; called by mutect2, varscan2
- CCDC181 | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100890256; called by muse, mutect2, varscan2
- CNTNAP4 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs758195382, COSV56665292; called by muse, mutect2, varscan2
- COQ5 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387361735, COSV99942186; called by muse, mutect2
- DHX16 | c.1165A>G p.K389E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.474); catalogued as COSV100905135; called by muse, mutect2, varscan2
- EML4 | c.1380G>T p.Q460H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100580711; called by muse, mutect2, varscan2
- ETV3 | c.185G>C p.G62A | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100460975; called by muse, mutect2, varscan2
- FARS2 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223957, COSV51165671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXD4L4 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1390496810; called by mutect2, varscan2
- FRMD3 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100418254; called by muse, mutect2, varscan2
- GRIK1 | c.1892T>C p.V631A | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV58715344; called by muse, mutect2
- HELB | c.271G>C p.V91L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV99921605; called by muse, mutect2, varscan2
- IFIT5 | c.789T>A p.N263K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100877917; called by muse, mutect2, varscan2
- IGHV1-18 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs1555449451; called by muse, mutect2, varscan2
- KCNJ8 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs762588905, COSV53716118, COSV99557432; called by muse, mutect2, varscan2
- KRR1 | c.1119T>G p.D373E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.022); catalogued as COSV99875505; called by muse, mutect2, varscan2
- LCE1C | c.251G>C p.R84T | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100908405, COSV64219291; called by muse, mutect2, varscan2
- MCM6 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs780556954, COSV99918755; called by muse, mutect2, varscan2
- MYO10 | c.5501G>T p.R1834L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99944757, COSV99946169; called by muse, mutect2, varscan2
- NDST2 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100013643; called by muse, mutect2, varscan2
- OR4A16 | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1438463805, COSV100125027; called by muse, mutect2, varscan2
- OR6K2 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100656698, COSV62743546; called by muse, mutect2, varscan2
- PCDH15 | c.2194G>T p.A732S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as COSV57274659; called by muse, mutect2, varscan2
- PCLO | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100427598, COSV61656856; called by muse, mutect2, varscan2
- PTPRC | c.3701G>A p.G1234E | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100722134, COSV61422374; called by muse, mutect2, varscan2
- SLC6A5 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs771753499, COSV100116456; called by muse, mutect2
- SPTA1 | c.4981G>T p.D1661Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100934298, COSV63753627; called by muse, mutect2, varscan2
- SPTA1 | c.2243A>G p.D748G | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.088); catalogued as COSV100934300; called by muse, mutect2, varscan2
- TAF1D | c.752A>C p.E251A | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as COSV100126656; called by muse, mutect2, varscan2
- TEX10 | c.2482dup p.V828Gfs*28 | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | catalogued as rs767307629; called by mutect2, pindel, varscan2
- UNC79 | c.7838G>A p.C2613Y (on ENST00000393151 / NM_001346218.2; = p.C2436Y on NM_020818.5) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as COSV99825953; called by muse, mutect2, varscan2
- UVSSA | c.1990C>T p.Q664* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as rs762345269, COSV101104316; called by muse, mutect2
- ZMYM4 | c.503del p.G168Efs*8 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs1195838634; called by mutect2, pindel*, varscan2
- CACNA2D4 | c.989_990del p.I330Sfs*4 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- AMZ1 | c.1449C>T p.L483= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs755974374, COSV56688565; called by muse, mutect2, varscan2
- CHRM3 | c.30G>A p.S10= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as rs1355967136, COSV99697564; called by muse, mutect2
- HRNR | c.1746T>A p.S582= | Silent (SNP) | VAF 28/228 reads (12%) | catalogued as COSV100912988; called by muse, mutect2, varscan2
- IGHG3 | c.306C>T p.T102= | Silent (SNP) | VAF 64/131 reads (49%) | catalogued as rs758271778; called by muse, mutect2, varscan2
- IL10RB | c.126A>G p.S42= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV99269786; called by muse, mutect2
- KCNG1 | c.393G>A p.L131= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs766719411, COSV100856983; called by muse, mutect2, varscan2
- MOCS2 | c.546C>T p.C182= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99670255; called by muse, mutect2, varscan2
- NGFR | c.225C>T p.D75= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as rs1472814572, COSV99412701; called by muse, mutect2
- NINJ1 | c.198C>T p.A66= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs372269819, COSV100966600; called by mutect2, varscan2
- PROX2 | c.676C>T p.L226= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV101507789; called by muse, mutect2, varscan2
- RRAS | c.630C>A p.G210= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs745391652, COSV55868725, COSV99881968; called by muse, mutect2, varscan2
- TPO | c.1464C>T p.A488= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs202005839, COSV61096934; called by muse, mutect2, varscan2
- NRP1 | c.981+4543T>G | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
